Somatic mutation profile of tumor specimen TCGA-CH-5765-01A (aliquot TCGA-CH-5765-01A-11D-1576-08) from TCGA case TCGA-CH-5765, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.8 years (20,364 days).
Specimen TCGA-CH-5765-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44ba62ab-f18c-404c-af5f-4407b0f7ffeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5765-11A (Solid Tissue Normal), aliquot TCGA-CH-5765-11A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdb751b3-a380-44e8-befe-ff11f5317e41

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 10, Nonsense Mutation 2, Splice Site 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKEF1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766863397, COSV65692332; called by muse, mutect2, varscan2
- ARID5A | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs775911272, COSV62591059; called by muse, mutect2, varscan2
- CHD6 | c.86A>G p.N29S | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.006); catalogued as COSV58556590; called by muse, mutect2, varscan2
- CLIP1 | c.2023G>T p.E675* (on ENST00000620786 / NM_001247997.1; = p.E664* on NM_002956.2) | Nonsense Mutation (SNP) | VAF 155/434 reads (36%) | catalogued as COSV56800718; called by muse, mutect2, varscan2
- CNDP1 | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV62593799; called by muse, mutect2, varscan2
- DDX19B | c.1012A>G p.I338V | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV55363810; called by muse, mutect2
- DHX57 | c.1234A>G p.I412V | Missense Mutation (SNP) | VAF 111/264 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as COSV54884763; called by muse, mutect2, varscan2
- DUSP16 | c.1181A>G p.N394S | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs529933489, COSV53807417; called by muse, mutect2, varscan2
- ERMAP | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs768412880, COSV60273683; called by muse, mutect2, varscan2
- GPATCH1 | c.1848C>A p.D616E | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as COSV50113729; called by muse, mutect2, varscan2
- GSKIP | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as rs755565686, COSV68451264; called by muse, mutect2, varscan2
- HNF1A | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs144674840, CM133578; called by muse, mutect2, varscan2
- MRPL20 | c.262G>T p.G88W | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV61224168; called by muse, mutect2
- MRPL38 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1297850621, COSV53932964; called by muse, mutect2, varscan2
- MYNN | c.829A>G p.I277V | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.456); catalogued as COSV62991229; called by muse, mutect2, varscan2
- NRCAM | c.1514A>T p.H505L (on ENST00000379028 / NM_001371124.1; = p.H499L on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV61035564; called by muse, mutect2, varscan2
- OR52R1 | c.267G>T p.W89C | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61888213; called by muse, mutect2, varscan2
- PCDHB5 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 32/501 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.08); catalogued as rs782266109, COSV50647266; called by muse, mutect2
- PDE8B | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1361375992, COSV53733826; called by muse, varscan2
- SORBS1 | c.209C>T p.A70V (on ENST00000361941 / NM_001034954.2; = p.A38V on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.197); catalogued as rs367690122; called by muse, mutect2, varscan2
- STAT4 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 46/128 reads (36%) | catalogued as COSV61828430; called by muse, mutect2, varscan2
- TNIP3 | c.736-1G>T p.X246_splice | Splice Site (SNP) | VAF 36/202 reads (18%) | catalogued as COSV50246154, COSV50247388; called by muse, mutect2, varscan2
- TPR | c.5913T>A p.D1971E | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs924908067, COSV66601036; called by muse, mutect2, varscan2
- ESCO1 | c.1399_1401del p.D467del | In Frame Del (DEL) | VAF 51/165 reads (31%) | called by mutect2, pindel, varscan2
- CBLIF | c.675T>C p.S225= | Silent (SNP) | VAF 63/180 reads (35%) | catalogued as COSV57238748, COSV57240423; called by muse, varscan2
- CCNF | c.1947C>T p.C649= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs751114062, COSV53539781; called by muse, mutect2, varscan2
- CHAMP1 | c.1164G>A p.E388= | Silent (SNP) | VAF 13/259 reads (5%) | catalogued as COSV63522265; called by muse, mutect2
- DIP2A | c.594A>T p.A198= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100595575; called by mutect2, varscan2
- EFS | c.1032G>A p.L344= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as rs763795252, COSV53732140; called by muse, mutect2
- FCRL5 | c.1608A>G p.S536= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV62513853; called by muse, mutect2, varscan2
- MTUS2 | c.831C>T p.S277= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs373502341; called by muse, mutect2, varscan2
- NOVA1 | c.1428A>G p.G476= | Silent (SNP) | VAF 56/157 reads (36%) | catalogued as COSV57475973; called by muse, mutect2, varscan2
- USH2A | c.8253C>T p.N2751= | Silent (SNP) | VAF 67/186 reads (36%) | catalogued as rs368877266; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF223 | c.117G>A p.E39= | Silent (SNP) | VAF 108/315 reads (34%) | catalogued as COSV71571867; called by muse, mutect2, varscan2
- FBN2 | c.*1C>A | 3'UTR (SNP) | VAF 38/234 reads (16%) | catalogued as COSV99326250; called by muse, varscan2
